CCDI case PBCHKF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/947042db-e4a7-4341-b95e-78db0d264b8f

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.6 years (585 days).

Biospecimens (3 samples)
- Sample 0DS52G: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DS534: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DS541: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
